Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-AC81, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-AC81-TTP1-A (Primary Tumor).

[page 1 of 10]
CAL PATHOLOGY CONSULTATION REPORT

Patient Name: [REDACTED]

DOB: [REDACTED]

Gender: [REDACTED]

Med Rec #: [REDACTED]

Physician: [REDACTED]

Client: [REDACTED]

Loc: [REDACTED]

Account: [REDACTED]

Accession No: [REDACTED]

Collected: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

+0

+0

+1

Specimen Source:

A: Right axillary sentinel lymph node

B: Right palpable lymph node

C: Right axillary contents

D: Right breast, mastectomy

FINAL DIAGNOSIS

- A. Right axillary anterior superficial lymph node, sentinel:
Two of three lymph nodes positive for metastatic carcinoma.
- B. Right lymph nodes, next to ribcage:
(2) lymph nodes positive for metastatic carcinoma.
Extranodal extension identified (1.3 cm).
- C. Right axillary contents:
Eight of twelve lymph nodes positive for metastatic carcinoma.
Extranodal extension identified.
- D. Right breast, mastectomy:
Infiltrating ductal carcinoma, poorly differentiated (8/9), 4.2 cm.
Type of DCIS: Solid.
Grade of DCIS: High-grade.
Extent of associated DCIS: 10% of tumor.
Margins: Free of tumor.
Angiolymphatic involvement: Present.
Lymph node status: Twelve of seventeen total lymph nodes positive for metastatic carcinoma.
Maximum size of lymph node metastases: 1.4 cm.
Extranodal extension: Present, 1.4 cm.
Receptor and oncogene studies pending.
AJCC pTNM Stage (6th Ed): pT2 pN2 pMX

[page 2 of 10]
Clinical History

Right breast mass with abnl mammogram et U/S. Core needle bx – infiltrating ductal CA, poorly differentiated.

Intraoperative Consultation

- A. Right axillary anterior superficial lymph node: Frozen section.
Diagnosis: (3) nodes, no tumor seen.
Reported to: [REDACTED]
- B. Right palpable lymph node, no radiation, next to ribcage: Frozen section.
Diagnosis: (2) nodes, both positive for carcinoma.
Reported to: [REDACTED]

Gross

- A. "Right axillary lymph nodes": 4.0 x 2.5 x 2.5 cm portion of fatty tissue with three lymph nodes, 0.6 to 1.5 cm. Representative portions are submitted for frozen section in one cassette with remaining lymphoid tissue in A1-3.
- B. "Right palpable lymph node": A 2.5 cm portion of fatty tissue with two indurated tan glistening lymph nodes 1.2 to 1.5 cm. ES,2C (all for frozen, each cassette – one node).
- C. "Right axillary contents": An irregular portion of fatty tissue, 4.2 cm diameter. There are approximately 18 lymph nodes 0.2 to 1.5 cm. At least four are partially replaced by indurated white glistening neoplasm varying between 0.4 and 0.8 cm diameter, at least two appearing matted. Code of sections:
- C1-3: Multiple small individual nodes.
- C4: Two lymph nodes, matted.
- C5: Individual node.
- C6-7: One lymph node per cassette.
- D. "Right breast": 21.0 x 12.0 x 5.0 cm, 914 gram breast with a 21.0 x 8.0 cm ellipse of skin displaying a grossly normal nipple and areola. Portions of the skin in the upper-outer quadrant, 6.5 cm from the nipple, appear moderately thickened and mottled over an area 6.5 cm. In the corresponding area, 2.0 cm from the deep margin is a tan ill-defined 4.2 x 2.9 x 2.5 cm neoplasm. The remaining breast has approximately 40% sclerotic breast tissue with a few small cysts. There are no lymph nodes. An additional 6.0 x 2.5 x 1.0 cm portion of fat is unremarkable. There are no lymph nodes. Code of sections:
- D1: Nipple.
- D2: Thickened area of skin.
- D3: Deep margin.
- D4-6: Cross section through tumor.
- D7: Additional tumor.
- D8: Upper outer quadrant.
- D9: Lower outer quadrant.
- D10: Lower inner quadrant.
- D11: Upper inner quadrant.

Microscopic

- A. Cross sections of lymph nodes show two foci in slides A1 and A3 (not in areas frozen) in two separate lymph nodes, with positivity for metastatic carcinoma.
- B. Step sections of two lymph nodes show near complete replacement of normal nodal architecture by metastatic carcinoma. The largest diameter of tumor is 1.3 cm and extranodal extension is seen, extending 1.2 cm in diameter in slide BFS2.
- C. Twelve lymph nodes are identified, with eight positive for metastatic carcinoma. In multiple areas, focal extranodal spread is seen.
- D. Nipple shows no tumor and the thickened area of skin demonstrates no carcinoma. A malignant epithelial neoplasm is identified on slides D4-D7, formed of cells exhibiting abundant eosinophilic cytoplasm, nuclear enlargement, hyperchromasia, and prominent nucleoli (nuclear grade 3/3), little tubule formation (architectural grade

[page 3 of 10]
3/3), and mitotic activity counted at 14 per 10 high-power fields (mitotic grade 2/3). Tumor infiltrates adipose tissue and demonstrates angiolymphatic invasion. Focal areas of microcalcifications are seen. Surgical margins are free of tumor. High-grade DCIS, of solid-type, is present, and comprises < 10% of the tumor. Random sections of breast show no additional neoplasm. Cystic dilatation of lobular structures is present, and relative increase in fibrosis is consistent with fibrocystic changes.

Procedures/Addenda

ADDENDUM

Addendum Diagnosis

Tissue submitted:

Right breast mass

Block # tested: D7

Date Ordered:

+4 Status: Signed Out

Date Complete:

+4

Date Reported:

+5

By

Hormone Receptor and Oncogene Analysis Immunohistochemical Technique

Antibody

Tumor Staining

Stain Intensity/Quality

Result

ER

30% %

Moderate/Heterogeneous

Positive/Favorable

PR

20% %

High/Heterogeneous

Positive/Favorable

Her-2

1+

Negative/No Overexpression

Seen.

NOTES:

ER/PR Reference Range: <5% negative, > or equal to 5% positive. Her-2 is scored 0 to 3+, and 2+ or 3+ are considered overexpression. % tumor staining is determined in immunoreactive areas only.

The clinical significance of ER/PR staining intensity and quality is not entirely clear at this time. It is possible that tumors with low intensity and/or heterogeneous staining may have different biologic behavior than tumors demonstrating strong homogeneous staining.

Despite appropriate positive and negative controls and observation for internal control staining, false-negative results are possible.

For estrogen and progesterone receptors, only staining of tumor cell nuclei is considered positive. For Her-2, only membrane staining is considered positive.

NOTE: The above test was developed and its performance characteristics determined by the laboratory at [redacted] has not been cleared or approved by the US Food & Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

Addendum Comment

{Not Entered}

ADDENDUM

Date Ordered:

+12 Status: Signed Out

Date Complete:

+12

Date Reported:

+12

By

Addendum Diagnosis

Results from

Body site:

Right breast.

Block tested:

D7

Her2 by FISH:

3.1 Amplified

Addendum Comment

Separate report from [redacted] has been forwarded to the clinician(s) and is available on file.

[page 4 of 10]
Hosp. Serv.:
Room/Bed:
P. Date:

Dict. MD:
Req. MD:
Req. MD:

+18

MR #:

Exam #:

Job Number: Version: 0

CT CHEST AND ABDOMEN

+18

CLINICAL INDICATION: Staging for right breast cancer.

TECHNIQUE: Routine CT scanning of the chest and abdomen down to the level of the iliac crests with intravenous contrast. Due to a power injector malfunction, only 90 cc of intravenous contrast were administered.

FINDINGS:

The level of enhancement appears adequate for diagnosis. There is a right breast fluid collection compatible with a postsurgical seroma which measures 11.7 x 4.3 cm in maximal transverse measurements. There are low density nodular opacities in the right axilla which could represent postsurgical fluid collections. This obscures any underlying lymph node or necrotic nodal metastasis. At the anterior aspect of the right thyroid gland is a soft tissue density nodule which is indeterminate in etiology, it measures 2.3 cm and could either be a thyroid nodule or a metastasis. At the posterior aspect of the right thyroid lobe appears to be a faintly visualized intrathyroidal nodule measuring about 1 cm. As clinically indicated, these findings could be further evaluated with thyroid ultrasound. No evidence for mediastinal or hilar lymphadenopathy. The lungs demonstrate two small, indeterminate noncalcified nodules. Both are on the order of about 3 mm. One is in the posterior segment right upper lobe and the other is in the posterior segment left upper lobe. Recommend followup CT scanning to evaluate for stability. At this point, the differential diagnosis is broad and includes granulomas, intraparenchymal lymph nodes, metastases, or less likely primary lung cancer.

Within the superior aspect of the right lobe of the liver is a low attenuation lesion measuring 1.7 cm. This is a nonspecific mass, it does measure higher density than a simple cyst. Differential diagnosis includes metastatic disease, high density cyst, or primary liver lesion. This is not in a location which would be amenable to percutaneous biopsy. I would recommend further characterization with liver MRI. No additional liver lesions. The spleen, pancreas, adrenal glands, and kidneys are normal. There is mild stranding around the splenic flexure of the colon which is nonspecific, correlate clinically for colitis such as ischemic colitis.

[page 5 of 10]
PATIENT

Job Number: Version: 0

CT CHEST AND ABDOMEN +18

IMPRESSION:

RIGHT BREAST SEROMA. THERE ARE ALSO SMALLER FLUID COLLECTIONS IN THE RIGHT AXILLARY REGION WHICH OBSCURE EVALUATION OF LYMPH NODES.

THERE ARE A COUPLE OF TINY LUNG NODULES WHICH ARE INDETERMINATE, FOLLOWUP RECOMMENDED.

SOFT TISSUE DENSITY NODULE ANTERIOR TO THE RIGHT LOBE OF THE THYROID GLAND AND ONE IN THE POSTERIOR ASPECT OF THE RIGHT LOBE THYROID GLAND, THESE ARE NONSPECIFIC NODULES, CONSIDER FURTHER EVALUATION WITH THYROID ULTRASOUND.

INDETERMINATE 1.7 CM LOW ATTENUATION LESION IN THE RIGHT LOBE OF THE LIVER. THIS COULD REPRESENT A METASTASIS. RECOMMEND FURTHER CHARACTERIZATION WITH LIVER MRI WITHOUT AND WITH INTRAVENOUS CONTRAST.

MILD STRANDING AROUND THE SPLENIC FLEXURE OF THE COLON, CORRELATE CLINICALLY FOR MILD COLITIS OR ISCHEMIC COLITIS.

CHC
D:
T:
J:
T:
cc:

[page 6 of 10]
Exam Date: [REDACTED] -16

Req. MD:

Version: 2

Page 1 of 1

BCC SCREEN MAMMO

Reason for Exam:

Screening.

Risk Factors:

No family history of breast cancer.

Physical Findings:

~60

-55 Patient states she fell in [REDACTED] large hematoma right breast. Physician stated [REDACTED] that it could be a loculated hematoma. Visually right lower quadrant "puckered" with arms raised. Approximate 7 cm x 7 cm firm, tender, "puckered" area. Scattered nodularities, bilaterally. Weight stable. [REDACTED] education given, monthly. Exam b [REDACTED]

Mammogram:

Technologist wa [REDACTED]

Bilateral CC, MLO view(s) were taken. Breast tissue is average. 5 cm spiculated mass right breast 10 o'clock. Suspicious calcifications associated. Probable cancer. CAD utilized; positive.

Assessment:

Incomplete: Need additional imaging evaluation.

Recommendation:

Ultrasound examination of the right breast.

[page 7 of 10]
P
N
D

Exam Date: [REDACTED] -16

Dict. MD: [REDACTED]

Req. MD: [REDACTED]

Version: 2 Page 2 of 2

BCC SCREEN MAMMO

T#: [REDACTED]

CC: [REDACTED]

[page 8 of 10]
Radiology

* Final Report *

* Final Report *

RADIOLOGY

PROCEDURE: CT CHEST AND ABDOMEN WITH INTRAVENOUS CONTRAST

INDICATIONS: Follow up metastases. Breast cancer.

COMPARISON: [REDACTED] +663

TECHNIQUE: Contrast-enhanced CT images were obtained through the chest and abdomen following intravenous administration of 100 cc Optiray 350 nonionic contrast.

FINDINGS:

CHEST:

NECK BASE: No interval change in a multilobulated and nodular right thyroid lobe and thyroid isthmus. These thyroid nodules are nonspecific on CT.

LUNGS: Negative for pulmonary nodules.

VASCULATURE: Within normal limits.

MEDIASTINUM/HILA: Within normal limits.

PLEURA: Within normal limits.

CHEST WALL: Postsurgical changes for right mastectomy. There is a left Port-A-Cath central line. The tip of the central line is in the superior vena cava.

AXILLA: Within normal limits.

MUSCULOSKELETAL: Normal for age.

ABDOMEN:

LIVER: Within normal limits. No focal liver lesion is identified on the current study.

BILIARY: Within normal limits.

PANCREAS: Within normal limits.

SPLEEN: No change in a small calcified nodule in the posterior inferior aspect of the spleen, compatible with a benign lesion.

KIDNEYS: Within normal limits.

ADRENALS: Within normal limits.

AORTA/VASCULAR: Within normal limits.

RETROPERITONEUM: Within normal limits.

BOWEL/MESENTERY: Within normal limits.

Printed by:
Printed on:

Page 1 of 2
(Continued)

[page 9 of 10]
Radiology

* Final Report *

ABDOMINAL WALL: Within normal limits.
PELVIC ORGANS: The patient is status post hysterectomy. No pelvic mass identified.
MUSCULOSKELETAL: Degenerative changes of the lumbar spine.

ADDITIONAL COMMENTS: None.

IMPRESSION: Stable CT scan of the chest, abdomen, and pelvis. No evidence for metastatic disease.

Completed Action List:

* Order by

Type: Radiology
Date: +865
Status: Auth (verified)
Title: RADIOLOGY +855 - +883
Encounter info: (BIA) Misc Ser & Chemo (P2),
Contributor system:

Printed by:
Printed on:

[page 10 of 10]
+3675

CT Chest/Abd/Pelvis w Contrast (BIA)

PROCEDURE: CT CHEST, ABDOMEN, AND PELVIS WITH CONTRAST

+2489

+2498 COMPARISON: [REDACTED] RMC, CT, CT PNL CHEST/ABD/PELVIS WITH CONTRAST, [REDACTED] US, US
+3098 SOFT TISSUE HEAD-NECK, [REDACTED] BC, MG MAMMO SCREEN
DIGITAL, [REDACTED] CT, CT PNL CHEST/ABD/PELVIS WITH
CONTRAST, [REDACTED] +3217

INDICATIONS: Breast cancer. Restaging.

PQRS QUALITY INFORMATION:

EXAM COUNT: 1 CT exams and 0 NM Myocardial Perfusion exams in past 12 months.

DATA AVAILABILITY: Dicom format image data is available to non-affiliated external entities on secure, media free, reciprocally searchable basis for 12 month period of time after the study.

DATA SEARCH: A search was conducted for prior patient CT exams performed at an external facility within 12 months prior to the imaging study being performed, and is available through a secure, authorized, media free, shared archive.

CT DOSE REGISTRY: CT study data has been reported to a CT Radiation Dose Index Registry containing all minimum necessary data elements.

Total Dose Length Product (DLP in mGy-cm): 1651.9

TECHNIQUE: CT scan of the chest, abdomen, and pelvis was performed with non-ionic intravenous contrast.

FINDINGS:

NECK BASE: Lobulated right thyroid nodule it is unchanged from prior exams.

LUNGS: Normal.

AORTA/VASCULAR: Minimal aortic calcification. Normal caliber aorta and pulmonary artery tree.

HILA/MEDIASTINUM: No enlarged adenopathy or mass. Small hiatal hernia.

CARDIAC: Normal.

PLEURA: Normal.

CHEST WALL/AXILLA: Right mastectomy. No axillary adenopathy. Stable appearing left breast parenchyma.

LIVER: Mild steatosis. No focal mass. 20 cm in length.

BILIARY: Tiny calcified gallstones. No gallbladder inflammation. Normal caliber common duct.

PANCREAS: Normal.

SPLEEN: Normal.

KIDNEYS: Normal.

ADRENALS: Normal.

RETROPERITONEUM: No enlarged adenopathy or mass.

BOWEL/MESENTERY: Normal.

ABDOMINAL WALL: Normal.

PELVIC ORGANS: Hysterectomy.

BONES: No destructive bony lesions. Thoracolumbar spondylosis. Prominent lower lumbar facet arthropathy without canal stenosis.

OTHER: Negative.

CONCLUSION: No evidence of metastatic disease in the chest, abdomen or pelvis. Changes of prior right mastectomy without evidence of chest wall recurrence.

Mildly enlarged fatty liver. Cholelithiasis. Small hiatal hernia.

Unchanged area nodules.

Dictated by [REDACTED]

Approved [REDACTED]

Approved by [REDACTED]

Source: NCI Genomic Data Commons file 31210c56-68c4-42e8-8d20-89678af0fb3a (ER0242 ER-AC81 Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).